Gene-level copy-number profile of tumor specimen TARGET-40-PANPUM-01A from TARGET case TARGET-40-PANPUM, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Pelvic bones, sacrum, coccyx and associated joints; Age at diagnosis: 16.4 years (5,996 days).
Specimen TARGET-40-PANPUM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-OS.09458d50-bcff-5763-8c45-248173385f91.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-40-PANPUM-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 418 have no estimate.
https://portal.gdc.cancer.gov/files/a277d1da-6981-424e-8567-e551288731b0

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 2,624; copy number 2: 12,513; copy number 3: 17,038; copy number 4: 21,401; copy number 5: 3,477; copy number 6: 2,040; copy number 7: 270; copy number 8: 299; copy number 9: 174; copy number 11: 16; copy number 12: 102; copy number 15: 14; copy number 17: 157; copy number 18: 63; copy number 22: 15.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:9,480,608–9,576,275, 2 genes: AC092821.1, AC092821.2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 541 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,811,186–88,861,563, 1 gene, copy number 12 (within-gene range 4–12): AC244205.1.
- chr2:88,857,161–89,117,844, 24 genes, copy number 12: IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17.
- chr13:23,465,776–23,676,104, 3 genes, copy number 9 (within-gene range 2–9): LINC00327, LINC00352, TNFRSF19.
- chr14:20,110,739–22,053,056, 144 genes, copy number 9–12 (broad region; genes not listed).
- chr14:22,415,362–24,115,010, 157 genes, copy number 17 (within-gene range 8–17) (broad region; genes not listed).
- chr19:6,887,566–7,294,414, 15 genes, copy number 22: ADGRE1, AC020895.2, AC020895.1, Metazoa_SRP, ADGRE4P, AC025278.1, AC025278.2, AC025278.3, MBD3L2B, MBD3L5, MBD3L4, MBD3L2, MBD3L3, ZNF557, INSR.
- chr19:12,559,571–13,906,452, 79 genes, copy number 11–18 (within-gene range 5–18) (broad region; genes not listed).
- chr19:14,789,260–15,584,709, 41 genes, copy number 9–12: OR7C1, AC005255.1, OR7A5, OR7A10, OR7A8P, OR7A2P, OR7A17, OR7A18P, OR7A1P, OR7A3P, OR7A11P, OR7A15P, OR7C2, SLC1A6, CCDC105, CASP14, OR1I1, SYDE1, ILVBL, AC003956.1, OR10B1P, RNU6-782P, NOTCH3, MIR6795, AC004257.1, EPHX3, BRD4, AC005776.1, AC005776.2, AKAP8, AC005785.1, AKAP8L, AC005785.2, AC006128.1, WIZ, MIR1470, RASAL3, PGLYRP2, CYP4F22, AC011492.1, CYP4F23P.
- chr19:27,638,483–27,984,984, 14 genes, copy number 15: ERVK-28, AC112702.1, LINC00662, AC006504.1, AC006504.5, AC006504.7, AC006504.3, SLC25A1P5, AC006504.2, AC006504.4, AC005357.2, AC006504.6, AC005758.1, AC005357.1.
- chr19:35,414,881–36,125,947, 63 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 253. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
